TCGA case TCGA-AZ-6601 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ad0617e-bc4a-4869-8419-744f04d9b7a3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 3,042 days (8.3 years).

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 68.7 years (25,082 days); Year of diagnosis: 2001; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,042 days (8.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 11; Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the colon (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Tumor of origin: diagnosis 1 of this record; Classification of tumor: Prior primary; Age at diagnosis: 74.9 years (27,352 days); Days to diagnosis: 2,270 days (6.2 years); AJCC staging edition: 4th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -1,132 days (-3.1 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 2,270 days (6.2 years); Residual disease: R0.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Prior malignancy of the bladder (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Day 2,270 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 2,270 days (6.2 years).
- Days to follow up: 3,042 days (8.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 1.8 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 162 cm; BMI: 22.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AZ-6601-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.4; Shortest dimension: 0.6.
  Slide TCGA-AZ-6601-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-AZ-6601-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-AZ-6601-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AZ-6601-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 2; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 1.8; Lymphovascular invasion indicator: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor.
- Other malignancy form 1: Malignancy type: Prior Malignancy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 3, Surgery: Days from index date to other malignancy surgery: -3281.
- Other malignancy form 3, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy prostate cancer treated w/ radiation. (Tumor sent to TCGA was from sigmoid colon.) Prior malignancy bladder cancer. Prior malignancy colon cancer. No systemic chemotherapy or radiation.
- Prior malignancy: Case indicates 3 prior malignancies. Prostate indicates locoregional therapy, previous colon cancer treatment was resection, it is unknown what type of treatment the patient had for bladder.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,042 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 3,042 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,270 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AZ-6601-01): tumor purity 0.46, ploidy 2, whole-genome doublings 0 (call status: legacy_call).
